FM case AD13217 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Paragangliomas and Glomus Tumors; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/38a2bb19-92b4-4a2d-84ed-ebc2d3ed916b

Male, 55.3 years: Pheochromocytoma, NOS (ICD-O-3 8700/0) of the adrenal gland; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
